CTSP case CTSP-AD4D — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c9e7505d-7fe1-4bc8-a9cd-7393974485e1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 57.5 years (21,020 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage III; Days to last follow up: 1,875 days (5.1 years); Best overall response: Partial Response; Ann Arbor extranodal involvement: No; Double expressor lymphoma: No; Double hit lymphoma: No; International Prognostic Index (IPI): Low-Intermediate Risk.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: DA-EPOCH-R; Days to treatment start: 10 days; Days to treatment end: 136 days; Treatment outcome: Partial Response; Reason treatment ended: Course of Therapy Completed; Treatment dose max: 3.
   Treatment given: Drug category: Growth factor.
   Treatment given: Therapeutic agents: Filgrastim.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; treatment (type not reported) (Methotrexate); treatment (type not reported) (Pegfilgrastim); adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (7 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 1,875 days (5.1 years); Disease response: Partial Response; Progression or recurrence: No; Days progression-free: 1,875 days (5.1 years); Adverse event: Peripheral Sensory Neuropathy; Adverse event grade: Grade 1.
- Days to follow up: 1,875 days (5.1 years); Adverse event: Platelet Count Decreased; Adverse event grade: Grade 1.
- Days to follow up: 1,875 days (5.1 years); Adverse event: Neutrophil Count Decreased; Adverse event grade: Grade 4.
- Days to follow up: 1,875 days (5.1 years); Adverse event: Anemia; Adverse event grade: Grade 1.
- Days to follow up: 1,875 days (5.1 years); Adverse event: Anemia; Adverse event grade: Grade 2.
- Days to follow up: 1,875 days (5.1 years); Adverse event: Thromboembolic Event; Adverse event grade: Grade 4.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL6 (FISH): Normal.
- Lactate Dehydrogenase 1393 [Blood test normal range upper: 190].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 180 cm; BMI: 28.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CTSP-AD4D-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample CTSP-AD4D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide CTSP-AD4D-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample DLBCL11362-sample: Sample type: Tumor; Tissue type: Tumor.
